Somatic mutation profile of tumor specimen 0DENCV from CCDI case PBBPVG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.7 years (5,382 days).
Specimen 0DENCV: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dd8615b-8cf6-45b5-9a56-1a6e7bddabb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DENBX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85a8248e-d989-47f5-adaf-c729ab7be85d

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, 3'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2459A>T p.D820V | Missense Mutation (SNP) | VAF 111/546 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913682, COSV55387023, COSV55391660, COSV55405326; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1062G>A p.K354= | Splice Region (SNP) | VAF 34/358 reads (9%) | catalogued as rs1131691118, CM143312, CS000871; ClinVar: likely pathogenic; called by muse, mutect2
- FUNDC2 | c.52C>G p.R18G | Missense Mutation (SNP) | VAF 72/765 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); called by muse, mutect2
- PPM1L | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 68/720 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TACR1 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 68/738 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- WDR61 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); called by muse, mutect2
- HUWE1 | c.5361G>A p.R1787= | Silent (SNP) | VAF 141/596 reads (24%) | catalogued as COSV99472870; called by muse, mutect2, varscan2
- SORBS3 | c.1485C>T p.R495= | Silent (SNP) | VAF 52/470 reads (11%) | called by muse, mutect2, varscan2
- ST8SIA2 | c.957G>A p.P319= | Silent (SNP) | VAF 109/582 reads (19%) | catalogued as rs201615346; called by muse, mutect2, varscan2
- CENPO | c.*2172C>T | 3'UTR (SNP) | VAF 26/221 reads (12%) | catalogued as rs768066518; called by muse, mutect2, varscan2
- WEE1 | c.1141+62G>T | Intron (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
